Surgical pathology report (de-identified scan), TCGA case TCGA-HW-8320, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site MSKCC, specimen TCGA-HW-8320-01A (Primary Tumor).

[page 1 of 2]
Ref. Source:

Clinical Diagnosis & History:

Seizures x 12 years right parietal intra-axial brain tumor, heterogenous solid and cystic.

Specimens Submitted:

- 1: Right parietal lobe brain tumor [REDACTED]
2: Right parietal lobe brain tumor #2

DIAGNOSIS:

1. Right parietal lobe brain tumor [REDACTED]:

Part # 1

TUMOR TYPE:

Anaplastic astrocytoma

WHO GRADE:

III

2. Right parietal lobe brain tumor #2:

Part # 2

TUMOR TYPE:

Anaplastic astrocytoma

WHO GRADE:

III

MOLECULAR TESTING / IMMUNOHISTOCHEMISTRY:

EGFR FISH has been ordered and results will be issued in a separate report

MGMT promoter methylation analysis has been ordered and results will be issued in a separate and results will be issued in a separate report

IDH and EGFR vIII testing has been ordered

Comment: While the majority of this tumor is low-grade, multiple mitotic figures are identified regionally, consistent with anaplastic (WHO grade III) transformation. In these same areas, MIB-1 immunostaining reveals a proliferation index exceeding 10%.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result

Special Stain
Unst_Recut
NEG CONT

Comment

[page 2 of 2]
IMM RECUT
MIB-1 (Ki-67)

Gross Description:

1. The specimen is received fresh for frozen section consultation, labeled "right parietal lobe brain" and consists of two pieces of soft myxoid tissue ranging from 0.5 cm to 1.5 cm. Representative section is submitted for frozen section and touch prep. The specimen is entirely submitted.

Summary of sections:
FSC - frozen section control
U - undesignated

2. The specimen is received fresh, labeled "right parietal lobe brain tumor number two", and consists of a 3.7 x 3.5 x 2.0 cm fragments of grey-white brain parenchyma admixed with hemorrhagic and tan-white soft myxoid tissue. The specimen is entirely submitted.

Summary of sections:
U - undesignated

Summary of Sections:

Part 1: Right parietal lobe brain tumor (fs)

Block	Sect. Site	PCs
1	fsc	1
1	U	1

Part 2: Right parietal lobe brain tumor #2

Block	Sect. Site	PCs
6	U	14

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen section diagnosis: Right parietal lobe brain tumor (fs): Low grade microcystic glioma.
Permanent diagnosis:

Source: NCI Genomic Data Commons file 015ee3a7-591e-4e52-8421-a3873dba7854 (TCGA-HW-8320.75564DAC-FB13-4214-B588-EC14C3550880.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).